Somatic mutation profile of tumor specimen TCGA-27-2528-01A (aliquot TCGA-27-2528-01A-01W-0837-08) from TCGA case TCGA-27-2528, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.6 years (22,867 days).
Specimen TCGA-27-2528-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d278908-6e5f-48d7-a93a-8eecc43b44b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-2528-10A (Blood Derived Normal), aliquot TCGA-27-2528-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de70eeab-850f-4cce-8695-9159b3cb29ca

The open-access MAF lists 61 somatic variants for this specimen: 51 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 8, Frame Shift Del 3, Frame Shift Ins 3, Nonsense Mutation 2, Intron 2, Splice Site 2, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 1374/1641 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by mutect2, varscan2
- WT1 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 334/992 reads (34%) | catalogued as rs121907909, CM971596, COSV60066326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58644502; called by muse, mutect2, varscan2
- ALPK2 | c.6219T>G p.S2073R | Missense Mutation (SNP) | VAF 192/715 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64493891; called by muse, mutect2, varscan2
- ANP32D | c.336A>C p.L112F | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV56980583; called by muse, mutect2, varscan2
- ATM | c.3279_3282del p.N1094Dfs*14 | Frame Shift Del (DEL) | VAF 104/378 reads (28%) | catalogued as rs879254281; called by pindel, varscan2
- BMP3 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 183/497 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51082815, COSV51086901; called by muse, mutect2, varscan2
- C3 | c.4325A>C p.N1442T | Missense Mutation (SNP) | VAF 257/897 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV55574750; called by muse, mutect2, varscan2
- CACNA1B | c.5531A>G p.H1844R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs759587821, COSV53130894; called by muse, mutect2, varscan2
- CELA3B | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 108/197 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs887057466, COSV61403460; called by muse, mutect2, varscan2
- CFAP47 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 84/110 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as rs1340321021, COSV52881153; called by muse, mutect2, varscan2
- CHID1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs373864240; called by muse, mutect2, varscan2
- CUL1 | c.1428C>G p.H476Q | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57389487; called by muse, mutect2, varscan2
- DNAH11 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs749125298, COSV60960806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs1021579404, COSV50015383; called by muse, mutect2, varscan2
- EFNB3 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs908477925, COSV56833660; called by muse, mutect2, varscan2
- EFS | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53732774; called by muse, mutect2, varscan2
- ENG | c.1733A>G p.D578G | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61227743; called by muse, mutect2, varscan2
- FAM90A1 | c.324-1G>A p.X108_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as rs747393897, COSV56712710; called by mutect2, varscan2
- FBXL5 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV58011925; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 66/134 reads (49%) | catalogued as rs752538869; called by mutect2, varscan2
- GABRA1 | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV50107615; called by muse, mutect2, varscan2
- GOT1L1 | c.870dup p.N291Qfs*89 | Frame Shift Ins (INS) | VAF 12/119 reads (10%) | catalogued as rs768946390; called by mutect2, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 16/147 reads (11%) | catalogued as rs748943611; called by mutect2, varscan2
- JMJD1C | c.5718A>T p.Q1906H | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59516032; called by muse, mutect2, varscan2
- LILRA2 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs372106807; called by muse, mutect2, varscan2
- NDST4 | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.974); catalogued as COSV52123520; called by muse, mutect2, varscan2
- NR4A1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770620910, COSV54483390; called by muse, mutect2, varscan2
- OR5W2 | c.581T>A p.V194D | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV60616573; called by muse, mutect2, varscan2
- PDCD11 | c.5402A>G p.Y1801C | Missense Mutation (SNP) | VAF 101/165 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs377470805; called by muse, mutect2, varscan2
- PTPRO | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.033); catalogued as rs755573133, COSV55512745; called by muse, mutect2, varscan2
- RBMY1E | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 139/317 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV62777119; called by muse, mutect2, varscan2
- SLC35D3 | c.1092G>T p.R364S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as COSV100090792, COSV59377894; called by muse, mutect2
- SLC4A5 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.232); catalogued as rs1553453865, COSV61028856; called by muse, mutect2, varscan2
- SP110 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144163010; called by muse, mutect2, varscan2
- SPAM1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1287492496, COSV56144734; called by muse, mutect2, varscan2
- SPTA1 | c.4264G>A p.D1422N | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV63754809; called by muse, mutect2, varscan2
- SYNE1 | c.5712G>T p.L1904F (on ENST00000367255 / NM_182961.4; = p.L1911F on NM_033071.3) | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54965735; called by muse, mutect2
- SYNE1 | c.4724T>A p.L1575H (on ENST00000367255 / NM_182961.4; = p.L1582H on NM_033071.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55008406; called by muse, mutect2, varscan2
- UGGT1 | c.3646G>A p.V1216M | Missense Mutation (SNP) | VAF 198/698 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs755677543, COSV52137090; called by muse, mutect2, varscan2
- ULK2 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 168/501 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1409308441, COSV64446364; called by muse, mutect2, varscan2
- UNC45B | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs529858933, COSV52093267, COSV52101965; called by muse, mutect2, varscan2
- ZNF683 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as rs374469495, COSV62874659; called by muse, mutect2
- ASB3 | c.355+1del p.X119_splice | Splice Site (DEL) | VAF 23/208 reads (11%) | called by mutect2, pindel, varscan2
- CNTN2 | c.1399_1400del p.V467Nfs*16 | Frame Shift Del (DEL) | VAF 28/237 reads (12%) | called by mutect2, pindel, varscan2
- H2BC6 | c.186_188dup p.I62dup | In Frame Ins (INS) | VAF 111/453 reads (25%) | called by mutect2, pindel, varscan2
- LSG1 | c.478A>T p.N160Y | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO9A | c.3605_3631del p.R1202_S1211delinsT | In Frame Del (DEL) | VAF 34/346 reads (10%) | called by mutect2, pindel
- PCDHGA7 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RAI14 | c.517del p.D173Ifs*32 | Frame Shift Del (DEL) | VAF 274/976 reads (28%) | called by mutect2, pindel, varscan2
- ZBED4 | c.2530C>T p.R844W | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPTF | c.2520T>C p.F840= | Silent (SNP) | VAF 64/186 reads (34%) | catalogued as COSV58839260; called by muse, mutect2, varscan2
- CPPED1 | c.639C>T p.I213= | Silent (SNP) | VAF 309/669 reads (46%) | catalogued as rs762127968, COSV55498497; called by muse, mutect2, varscan2
- FOXM1 | c.876C>T p.H292= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as rs373291558; called by muse, mutect2, varscan2
- NTSR1 | c.813C>T p.A271= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs377415240; called by muse, mutect2, varscan2
- OBSCN | c.8136C>T p.D2712= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs766926346, COSV52784578; called by muse, mutect2
- PCDHB5 | c.1896C>T p.R632= | Silent (SNP) | VAF 71/181 reads (39%) | catalogued as COSV50654939; called by muse, mutect2, varscan2
- UGT3A2 | c.1458C>T p.L486= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs762343800, COSV56928972; called by muse, mutect2, varscan2
- WDR48 | c.1332T>G p.S444= | Silent (SNP) | VAF 68/235 reads (29%) | catalogued as COSV56532534; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33843C>T | Intron (SNP) | VAF 130/352 reads (37%) | catalogued as rs1396156223, COSV100280969; called by muse, mutect2, varscan2
- DCAF6 | c.1379-15334C>T | Intron (SNP) | VAF 34/107 reads (32%) | catalogued as rs371524406; called by muse, mutect2, varscan2
